Gene-level copy-number profile of tumor specimen MP2PRT-PASGZN-TMP1-A from MP2PRT case MP2PRT-PASGZN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,282 days).
Specimen MP2PRT-PASGZN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file df443e28-f7fe-4a0d-bbf0-98c33675dcbf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASGZN-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,257 have no estimate.
https://portal.gdc.cancer.gov/files/eb4a9d98-3907-4224-b8af-430140bb0b60

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 289; copy number 1: 594; copy number 2: 57,251; copy number 3: 223; copy number 4: 9.

Homozygous deletions (total copy number 0; autosomes only): 289 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,297,785, 48 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37.
- chr3:121,769,761–121,835,079, 1 gene: IQCB1.
- chr3:177,010,719–178,007,779, 18 genes: MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P.
- chr4:49,486,926–49,489,554, 1 gene: AC119751.3.
- chr7:50,304,068–50,405,101, 2 genes: IKZF1, AC124014.1.
- chr14:22,449,113–22,459,156, 5 genes (within-gene range 0–2): TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3.
- chr14:22,483,004–22,507,723, 20 genes (within-gene range 0–2): TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34.
- chr14:105,672,308–106,637,973, 152 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,657,725–106,672,073, 3 genes (within-gene range 0–1): IGHV3-64, IGHV3-65, IGHVII-65-1.
- chr21:38,380,027–39,062,894, 13 genes: ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.2.
- chr22:22,738,944–22,755,797, 3 genes (within-gene range 0–2): IGLV3-17, IGLV3-16, IGLV3-15.
- chr22:22,762,294–22,787,268, 4 genes (within-gene range 0–2): IGLV3-13, IGLV3-12, AC244157.1, AC244157.2.
- chr22:22,803,076–22,901,437, 19 genes (within-gene range 0–2): AC245028.3, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571, IGLL5, IGLJ1, IGLC1, IGLJ2, IGLC2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 594. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
